Gene-level copy-number profile of tumor specimen TCGA-EA-A50E-01A from TCGA case TCGA-EA-A50E, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 45.5 years (16,609 days).
Specimen TCGA-EA-A50E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.f61e5a2f-668e-42b0-a6ad-209c7cb0e956.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EA-A50E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c0f27360-141f-431c-8a78-c344f1ecaed6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 7; copy number 2: 7,099; copy number 3: 21; copy number 4: 47,118; copy number 6: 5,166; copy number 7: 198; copy number 8: 18; copy number 10: 2; copy number 14: 174.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EA-A50E-01A-21D-A26F-01): tumor purity 0.5, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,581,357–213,021,545, 7 genes (within-gene range 0–2): AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2.
- chr3:59,464,330–61,251,459, 10 genes (within-gene range 0–2): AC126121.2, AC126121.1, Metazoa_SRP, FHIT, AC093418.1, AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 176 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:73,399,031–73,408,352, 2 genes, copy number 10: AL162376.1, MARK2P12.
- chr19:36,604,817–40,226,697, 174 genes, copy number 14 (within-gene range 7–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
